FM case AD9552 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Acinar Cell Neoplasms; Primary site: Prostate gland.
https://portal.gdc.cancer.gov/cases/4d061ab4-5b09-4053-848a-e6feffb5388f

Male, 51.6 years: Acinar adenocarcinoma (ICD-O-3 8550/3) of the prostate gland; primary biopsied or resected from the prostate gland. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
